Somatic mutation profile of tumor specimen TCGA-DK-A3IV-01A (aliquot TCGA-DK-A3IV-01A-22D-A21A-08) from TCGA case TCGA-DK-A3IV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 60.9 years (22,237 days).
Specimen TCGA-DK-A3IV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 359c63e4-e9c5-4386-9f47-dbb9038f262a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3IV-10A (Blood Derived Normal), aliquot TCGA-DK-A3IV-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca61a613-a530-473c-9459-7dfbb868be8c

The open-access MAF lists 78 somatic variants for this specimen: 58 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 17, Nonsense Mutation 6, Intron 2, Frame Shift Del 2, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 18/50 reads (36%) | hotspot (GDC flag); catalogued as rs587776783, CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASPM | c.9842G>A p.R3281K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV54138360; called by muse, mutect2, varscan2
- CASD1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV51975337; called by muse, mutect2, varscan2
- CCDC110 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1183836457, COSV56873318; called by muse, mutect2, varscan2
- CD164L2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs992932439, COSV64995708; called by muse, mutect2
- CDR1 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV65164788; called by muse, mutect2
- CHAC1 | c.26A>T p.N9I | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV71436251; called by muse, mutect2, varscan2
- DHX29 | c.862C>G p.Q288E | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.038); catalogued as COSV52422005; called by muse, mutect2
- DNAH10 | c.6708C>G p.I2236M (on ENST00000409039; = p.I2175M on NM_207437.3) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV69001083; called by muse, mutect2, varscan2
- DNAH11 | c.5033G>C p.G1678A | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.753); catalogued as COSV60968043; called by muse, mutect2
- ELP1 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV65899858; called by muse, mutect2, varscan2
- FANCD2 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs150217066; called by muse, mutect2, varscan2
- GABRR2 | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.02); catalogued as COSV68766252; called by muse, mutect2, varscan2
- GAREM1 | c.2245G>A p.D749N (on ENST00000269209 / NM_001242409.2; = p.D748N on NM_022751.3) | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.631); catalogued as COSV52515738; called by muse, mutect2, varscan2
- GCNT4 | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV59281705; called by muse, mutect2, varscan2
- GRAMD1C | c.561C>G p.F187L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as COSV63984493; called by muse, mutect2, varscan2
- HAND2 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV104422196, COSV64019074; called by muse, mutect2, varscan2
- HMGCLL1 | c.785T>A p.M262K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51451617; called by muse, mutect2, varscan2
- HOXC4 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV57700548; called by muse, mutect2, varscan2
- IRS4 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV64535904; called by muse, mutect2
- ITGB4 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.72); catalogued as rs201532846, COSV52332352; called by muse, mutect2, varscan2
- KCTD16 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV72580480, COSV99081801; called by muse, mutect2, varscan2
- KIF23 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); catalogued as rs187707408, COSV52982996; called by muse, mutect2, varscan2
- NOCT | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54936924; called by muse, mutect2, varscan2
- NUP210 | c.4532C>T p.S1511L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs1286027137, COSV54413716; called by muse, mutect2, varscan2
- OR14K1 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV51722386; called by muse, mutect2, varscan2
- OSBPL8 | c.2203G>C p.D735H | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53888924; called by muse, mutect2, varscan2
- OTX2 | c.526C>T p.P176S (on ENST00000408990 / NM_172337.3; = p.P184S on NM_021728.4) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.129); catalogued as rs751820068, COSV59767533; called by muse, mutect2, varscan2
- PANK1 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333465002, COSV56810456; called by muse, mutect2
- PBX2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV66709375; called by muse, mutect2, varscan2
- PDILT | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 58/412 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV56705127; called by muse, mutect2, varscan2
- PDZD2 | c.3092C>T p.S1031L | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs758169969, COSV56872038; called by muse, mutect2, varscan2
- PKD1L1 | c.8438C>G p.P2813R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs748675283, COSV51844986; called by muse, mutect2, varscan2
- PPFIA4 | c.2092G>A p.E698K (on ENST00000447715; = p.E699K on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV55321430; called by muse, mutect2, varscan2
- RBP1 | c.360G>A p.M120I (on ENST00000619087 / NM_001365940.2; = p.M182I on NM_002899.5) | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV51678439; called by muse, mutect2, varscan2
- RXYLT1 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.154); catalogued as COSV54170013; called by muse, mutect2, varscan2
- SCGN | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV58547112; called by muse, mutect2, varscan2
- SMTNL2 | c.496G>A p.D166N (on ENST00000389313 / NM_001114974.2; = p.D22N on NM_198501.3) | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs755326541, COSV100130925, COSV58808184; called by muse, mutect2, varscan2
- SRC | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); catalogued as COSV62441153; called by muse, mutect2, varscan2
- SYTL2 | c.1994C>G p.S665* (on ENST00000528231 / NM_001162951.2; = p.S641* on NM_032943.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 50/110 reads (45%) | catalogued as COSV60356465; called by muse, mutect2, varscan2
- TAF6 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV59843792; called by muse, mutect2, varscan2
- TAS1R3 | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as COSV59564499; called by muse, mutect2, varscan2
- TENM4 | c.4116C>G p.I1372M | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53667797, COSV53676496; called by muse, mutect2, varscan2
- TFG | c.726G>C p.Q242H | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs755002578, COSV52550774; called by muse, varscan2
- TSPYL1 | c.785G>C p.R262P | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs928784250, COSV63994290; called by muse, mutect2, varscan2
- TUBA3C | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as COSV67139954; called by muse, mutect2, varscan2
- UGT2B28 | c.1387T>A p.W463R | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59434303; called by muse, mutect2, varscan2
- ZNF229 | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.821); catalogued as COSV52164779; called by muse, mutect2, varscan2
- ZNF248 | c.1178C>G p.S393* | Nonsense Mutation (SNP) | VAF 24/105 reads (23%) | catalogued as COSV100627533; called by muse, mutect2, varscan2
- ZNF282 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309729406, COSV50483609; called by muse, mutect2, varscan2
- ZNF611 | c.899C>A p.S300* | Nonsense Mutation (SNP) | VAF 29/262 reads (11%) | catalogued as COSV60543621; called by muse, mutect2, varscan2
- CDKN1A | c.250_257del p.R84Gfs*2 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- CROT | c.1055G>C p.R352T | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2
- DCBLD2 | c.1255A>G p.N419D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FEM1A | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- FOXD2 | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 61/220 reads (28%) | called by muse, mutect2, varscan2
- WBP11 | c.1506_1521del p.R503Afs*27 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | called by mutect2, pindel
- ACADSB | c.60G>T p.L20= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV62551457; called by muse, mutect2, varscan2
- AKAP7 | c.549G>A p.L183= | Silent (SNP) | VAF 40/169 reads (24%) | catalogued as COSV63505827; called by muse, mutect2, varscan2
- BCL2L13 | c.1290G>A p.E430= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV58227537; called by muse, mutect2, varscan2
- C9orf64 | c.306G>T p.L102= | Silent (SNP) | VAF 40/220 reads (18%) | catalogued as COSV59033151; called by muse, mutect2, varscan2
- DEPDC1B | c.1440C>T p.S480= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99409734; called by muse, mutect2
- EFCAB5 | c.1488G>A p.Q496= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV57937033; called by muse, mutect2, varscan2
- GNAZ | c.183C>T p.F61= | Silent (SNP) | VAF 71/186 reads (38%) | catalogued as COSV50741564; called by muse, mutect2, varscan2
- KCNQ2 | c.1644C>T p.F548= (on ENST00000359125 / NM_172107.4; = p.F520= on NM_004518.6) | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as rs1241388377, COSV60553869; called by muse, mutect2, varscan2
- LIPE | c.48A>G p.E16= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV54925350; called by muse, mutect2, varscan2
- MDGA2 | c.1449G>A p.T483= (on ENST00000399232 / NM_001113498.2; = p.T185= on NM_182830.4) | Silent (SNP) | VAF 45/185 reads (24%) | catalogued as rs774276862, COSV62109259; called by muse, mutect2, varscan2
- MED13 | c.6288T>C p.L2096= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as COSV67266939; called by muse, mutect2, varscan2
- NFASC | c.2451C>T p.I817= (on ENST00000339876 / NM_001378329.1; = p.I813= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs576309017, COSV58379412; called by muse, mutect2, varscan2
- PIGC | c.822T>C p.L274= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV51130937; called by muse, mutect2, varscan2
- SDSL | c.651C>G p.V217= | Silent (SNP) | VAF 40/266 reads (15%) | catalogued as COSV61885308; called by muse, mutect2, varscan2
- SIPA1L3 | c.1563G>A p.E521= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs1237491755, COSV55912728, COSV55923765; called by muse, mutect2, varscan2
- TFAP2B | c.270C>T p.N90= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as rs759283766, COSV53831211; called by muse, mutect2, varscan2
- ZNF628 | c.1059G>T p.A353= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs1196607535, COSV52700477; called by muse, varscan2
- AC017104.4 | chr2:231509194 C>A | 5'Flank (SNP) | VAF 78/221 reads (35%) | called by muse, mutect2, varscan2
- AQR | c.471+944G>A | Intron (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10360+4074C>G | Intron (SNP) | VAF 5/50 reads (10%) | catalogued as COSV60019954; called by muse, mutect2
